Somatic mutation profile of tumor specimen 0E0THI from CCDI case PBCVLY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0THI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0b1d604-a3bf-40a3-bc4c-7e93fe475de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0THQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0943b93d-d6d6-4eec-9d31-e8ba4bb41fa1

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/434 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CHSY1 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as rs984872328, COSV99573826; called by muse, mutect2, varscan2
- CD19 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLSPN | c.2712G>A p.M904I | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CYP2A7 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 17/512 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- INPP5J | c.1612-6C>A | Splice Region (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2, varscan2
- KATNAL2 | c.1391C>T p.S464L (on ENST00000356157 / NM_001353899.1; = p.S392L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/520 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NFKBIB | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XYLT1 | c.1588-84G>C | Intron (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
